Somatic mutation profile of tumor specimen TCGA-VQ-A91N-01A (aliquot TCGA-VQ-A91N-01A-11D-A410-08) from TCGA case TCGA-VQ-A91N, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 59.6 years (21,753 days).
Specimen TCGA-VQ-A91N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 329f3956-c1b7-49d8-aac1-ee7c8ad611b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91N-10A (Blood Derived Normal), aliquot TCGA-VQ-A91N-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cbc5471-ce0d-481e-bb87-ef6c1db01989

The open-access MAF lists 121 somatic variants for this specimen: 83 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 36, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD9 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs748222640, COSV100459075; called by muse, varscan2
- ADAMTS9 | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs374662732; called by muse, mutect2, varscan2
- ARF1 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV99683113; called by muse, mutect2, varscan2
- ASIC1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57320235; called by muse, mutect2, varscan2
- ASIC5 | c.954A>C p.E318D | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV101611124; called by muse, mutect2, varscan2
- BCOR | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100653114; called by muse, mutect2, varscan2
- BDKRB1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 54/80 reads (68%) | catalogued as rs372328639; called by muse, mutect2, varscan2
- BTD | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100329490; called by muse, mutect2
- C2orf16 | c.4090G>A p.A1364T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV62679294; called by muse, mutect2, varscan2
- C4BPA | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV100891180; called by muse, mutect2, varscan2
- CACNA2D3 | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV55522840, COSV99872116; called by muse, mutect2, varscan2
- CAPS2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs562989650, COSV60824200; called by muse, mutect2, varscan2
- CARD17 | c.318A>G p.I106M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100995201; called by muse, mutect2, varscan2
- CDH8 | c.1518A>T p.E506D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs1335637090, COSV100180691; called by muse, mutect2, varscan2
- CDYL | c.1524G>T p.K508N (on ENST00000328908 / NM_001368125.1; = p.K454N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100189088; called by muse, mutect2, varscan2
- CLSTN2 | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs560530846, COSV71722438; called by muse, mutect2, varscan2
- CMKLR1 | c.461G>A p.R154H (on ENST00000312143 / NM_001142344.2; = p.R152H on NM_004072.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs749502814, COSV100379298, COSV56436930; called by muse, mutect2, varscan2
- CNTNAP3 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375331959; called by muse, mutect2, varscan2
- DDIAS | c.2793A>T p.K931N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV100231115; called by muse, varscan2
- DHX16 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757748798, COSV64564008; called by muse, mutect2, varscan2
- DNAH3 | c.5150C>G p.T1717S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV99766208; called by muse, mutect2, varscan2
- DNAH5 | c.9686A>G p.K3229R | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99447750; called by muse, mutect2
- DSEL | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as COSV59489958; called by muse, mutect2, varscan2
- DSG1 | c.3018G>T p.L1006F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV99935779; called by muse, mutect2, varscan2
- DSP | c.8472_8483del p.S2843_R2846del | In Frame Del (DEL) | VAF 46/101 reads (46%) | catalogued as rs397516967; ClinVar: uncertain significance / likely benign; called by mutect2, pindel, varscan2
- EP400 | c.5137C>T p.R1713C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754032425, COSV100200908, COSV100201186; called by muse, mutect2, varscan2
- FILIP1 | c.3095T>A p.M1032K | Missense Mutation (SNP) | VAF 80/128 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs766680260, COSV99384389; called by muse, mutect2, varscan2
- FLG | c.8305C>A p.Q2769K | Missense Mutation (SNP) | VAF 175/611 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as COSV100911381; called by muse, mutect2, varscan2
- GRK7 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99379718; called by muse, mutect2, varscan2
- H1-5 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58899214, COSV58899740, COSV58899833; called by muse, mutect2, varscan2
- HR | c.2632C>G p.Q878E | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100455749; called by muse, mutect2, varscan2
- INTS13 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 97/117 reads (83%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1269334777, COSV53903291; called by muse, mutect2, varscan2
- ITIH6 | c.2791T>A p.F931I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV99513103; called by muse, mutect2, varscan2
- ITPRID2 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs112676123; called by muse, mutect2, varscan2
- JAG1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs375017114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5C | c.1524C>G p.F508L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100948983; called by muse, mutect2, varscan2
- KIF16B | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV100734057; called by muse, mutect2, varscan2
- KIF26B | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831989; called by muse, mutect2
- KLHL1 | c.1459A>G p.I487V | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV100917131, COSV64777801; called by muse, mutect2, varscan2
- LAMB2 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs746765362; called by muse, mutect2
- LRP1B | c.8832C>A p.D2944E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769739604, COSV67231802, COSV67281562; called by muse, mutect2, varscan2
- MAOA | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs779805250, COSV58643180; called by mutect2, varscan2
- MST1R | c.2049G>A p.E683= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99618342; called by muse, mutect2, varscan2
- MYO15A | c.7705T>G p.F2569V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as COSV52761422, COSV99232000; called by mutect2, varscan2
- NAP1L1 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs757630325, COSV53874253; called by muse, mutect2, varscan2
- NPR1 | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100902005; called by muse, mutect2, varscan2
- NRG3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764611896, COSV64545820, COSV64548799; called by muse, mutect2, varscan2
- NYNRIN | c.4678G>A p.E1560K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs778733327, COSV101230557; called by muse, mutect2, varscan2
- OR4C13 | c.898T>C p.C300R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV101634156; called by muse, mutect2, varscan2
- OR5D13 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV62333075; called by muse, mutect2, varscan2
- OR8A1 | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.07); catalogued as COSV99420463; called by muse, mutect2, varscan2
- ORC1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1239496219, COSV100856638; called by muse, mutect2, varscan2
- PDGFRL | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 116/188 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99286273; called by muse, mutect2, varscan2
- PGM2 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs764111980, COSV67939264; called by muse, mutect2, varscan2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- POLR3G | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV101209780; called by muse, mutect2, varscan2
- PREB | c.597T>G p.I199M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV99574404; called by muse, mutect2, varscan2
- PREX2 | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200020354, COSV55748902; called by muse, mutect2, varscan2
- PSPC1 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs78767665, COSV100142240; called by muse, mutect2, varscan2
- RFTN1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100489091; called by muse, mutect2, varscan2
- RGL1 | c.1748dup p.L584Afs*3 (on ENST00000360851 / NM_001297672.2; = p.L619Afs*3 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/38 reads (58%) | catalogued as rs1217653266; called by mutect2, varscan2
- RIMBP2 | c.724A>C p.T242P | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as COSV99898981; called by muse, mutect2, varscan2
- SGCZ | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV101168152; called by muse, mutect2
- SORCS3 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV100864942; called by muse, mutect2, varscan2
- SPATA4 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as COSV54589408; called by muse, mutect2, varscan2
- STAB2 | c.1625A>G p.H542R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV66337369; called by muse, mutect2, varscan2
- STK39 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.413); catalogued as COSV100596441; called by muse, mutect2, varscan2
- STX11 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1469614986, COSV62449822; called by muse, mutect2, varscan2
- SUGP1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs775710080, COSV55920434; called by muse, mutect2, varscan2
- SYNE1 | c.2983C>A p.Q995K (on ENST00000367255 / NM_182961.4; = p.Q1002K on NM_033071.3) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99558987; called by muse, mutect2, varscan2
- TAP2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as rs756271450, COSV100886843; called by muse, mutect2, varscan2
- TEKT3 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1039031628, COSV100106963; called by muse, mutect2, varscan2
- TMCC2 | c.1796A>G p.Y599C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs764420807, COSV100319248; called by muse, mutect2, varscan2
- TP53 | c.880del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 27/50 reads (54%) | catalogued as CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; called by mutect2, pindel, varscan2
- TRIM13 | c.885T>G p.D295E | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV100078253; called by muse, mutect2, varscan2
- TRIM35 | c.293C>G p.S98W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1278773656, COSV100542711; called by muse, mutect2, varscan2
- TRPV4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs777647151, COSV99924563; called by muse, mutect2, varscan2
- ZNF257 | c.1229A>T p.N410I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101448077; called by muse, mutect2, varscan2
- ZNF546 | c.2504T>C p.I835T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61258047; called by muse, mutect2, varscan2
- GDPD1 | c.691_710del p.M231Afs*19 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- LYZ | c.412_413del p.D138Cfs*33 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- PCDHGB5 | c.2315G>C p.G772A | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB11FIP3 | c.1179_1180dup p.G394Afs*50 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ADGRL2 | c.4101C>T p.N1367= (on ENST00000370717 / NM_001366005.1; = p.N1311= on NM_012302.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99588081; called by muse, mutect2, varscan2
- ALPK2 | c.6127A>C p.R2043= | Silent (SNP) | VAF 54/191 reads (28%) | catalogued as COSV100864267; called by muse, mutect2, varscan2
- ASH1L | c.96C>T p.V32= | Silent (SNP) | VAF 124/238 reads (52%) | catalogued as COSV100853297; called by muse, mutect2, varscan2
- BAG6 | c.852C>G p.L284= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV52988576; called by muse, mutect2, varscan2
- BRINP3 | c.927C>A p.T309= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV66531505; called by muse, mutect2
- BRPF1 | c.1239C>T p.C413= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs780323655, COSV57408204; called by muse, mutect2, varscan2
- CCDC124 | c.582G>A p.S194= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1468564825, COSV101506486; called by muse, mutect2, varscan2
- CCNA1 | c.792C>A p.T264= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV99714457; called by muse, mutect2, varscan2
- CD226 | c.699C>G p.T233= | Silent (SNP) | VAF 35/217 reads (16%) | catalogued as COSV99710985; called by muse, mutect2, varscan2
- COL17A1 | c.2748C>A p.P916= | Silent (SNP) | VAF 221/336 reads (66%) | catalogued as rs763708555, COSV100793114; called by muse, varscan2
- COL17A1 | c.2706C>G p.T902= | Silent (SNP) | VAF 165/252 reads (65%) | catalogued as COSV100793116; called by muse, varscan2
- DLD | c.1338G>A p.S446= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs1323254312, COSV99226966; called by muse, mutect2, varscan2
- DNAJC16 | c.1890G>A p.S630= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs369927925; called by muse, mutect2, varscan2
- DOCK2 | c.2952G>A p.V984= | Silent (SNP) | VAF 86/154 reads (56%) | catalogued as rs780984158, COSV99911376; called by muse, mutect2, varscan2
- ELAVL4 | c.411C>T p.S137= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs374149997; called by muse, mutect2, varscan2
- F5 | c.5502C>T p.G1834= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs141434073; called by muse, mutect2, varscan2
- HCAR3 | c.1068T>G p.S356= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV100811548; called by muse, mutect2, varscan2
- IGKV6D-41 | c.174G>A p.Q58= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- IRGC | c.1170C>T p.N390= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs902214912, COSV99746205; called by muse, mutect2, varscan2
- LCE5A | c.192T>G p.G64= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV100524217, COSV100524298; called by muse, mutect2
- LGI2 | c.1608T>C p.F536= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV101180799; called by muse, mutect2, varscan2
- LRRTM1 | c.1026C>T p.C342= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs923586880, COSV54445993; called by muse, mutect2, varscan2
- MUC16 | c.21183T>C p.T7061= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV101199290, COSV67467087; called by muse, mutect2, varscan2
- NANP | c.531C>T p.L177= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as rs138863137; called by muse, mutect2, varscan2
- PANX2 | c.393C>T p.F131= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1288190332, COSV99348133; called by muse, mutect2
- PCDHB3 | c.1035G>A p.P345= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1412518919, COSV50585910; called by muse, mutect2, varscan2
- PDE4B | c.480C>T p.H160= | Silent (SNP) | VAF 45/206 reads (22%) | catalogued as rs372187760; called by muse, mutect2, varscan2
- PRDM4 | c.225T>C p.G75= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99946510; called by muse, mutect2, varscan2
- RPS6KA3 | c.304T>C p.L102= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs757971865, COSV101084264; called by muse, mutect2, varscan2
- SHANK2 | c.2865G>A p.E955= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs1555154468, COSV99573164; called by muse, mutect2, varscan2
- SMC1A | c.1749G>A p.E583= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100447240; called by muse, mutect2, varscan2
- TSHZ3 | c.2520C>T p.R840= | Silent (SNP) | VAF 46/196 reads (23%) | catalogued as rs373110206; called by muse, mutect2, varscan2
- UBN1 | c.1941C>T p.G647= | Silent (SNP) | VAF 9/158 reads (6%) | catalogued as rs1471091067, COSV99277744; called by muse, mutect2
- USP31 | c.1024C>T p.L342= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99564930; called by muse, mutect2, varscan2
- USP34 | c.1299C>T p.I433= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV101276883; called by muse, mutect2
- ZFP2 | c.318G>A p.Q106= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100797032; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+1010T>C | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99759803; called by muse, mutect2
- KLHL4 | c.*2793A>C | 3'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100909377; called by muse, varscan2
